Gene-level copy-number profile of tumor specimen TCGA-A7-A13F-01A from TCGA case TCGA-A7-A13F, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 44.8 years (16,363 days).
Specimen TCGA-A7-A13F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.b2b8924a-2ad1-4463-9b5d-c6c5609318ef.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A13F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e62f93f3-c8d1-46dd-b24c-db5bbeb66bba

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 6,133; copy number 3: 20,429; copy number 4: 11,465; copy number 5: 11,864; copy number 6: 7,052; copy number 7: 2,555; copy number 9: 13; copy number 12: 25; copy number 13: 22; copy number 14: 8; copy number 15: 11; copy number 16: 127; copy number 18: 24; copy number 20: 66; copy number 32: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A13F-01A-11D-A12N-01): tumor purity 0.65, ploidy 3.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,873 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–227,482,454, 2,066 genes, copy number 7 (broad region; genes not listed).
- chr1:228,464,103–248,919,946, 489 genes, copy number 7 (broad region; genes not listed).
- chr20:37,444,733–38,033,461, 13 genes, copy number 12: RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1.
- chr20:40,685,848–41,383,107, 17 genes, copy number 16: MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1.
- chr20:44,496,221–46,550,654, 98 genes, copy number 16 (within-gene range 6–16) (broad region; genes not listed).
- chr20:50,081,124–50,429,483, 11 genes, copy number 15 (within-gene range 3–15): PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P.
- chr20:50,645,471–51,098,845, 12 genes, copy number 16: RIPOR3-AS1, PARD6B, BCAS4, TMSB4XP6, ADNP, PSMD10P1, ADNP-AS1, DPM1, MOCS3, AL050404.1, KCNG1, AL121785.1.
- chr20:51,386,957–59,847,711, 150 genes, copy number 9–32 (within-gene range 5–32) (broad region; genes not listed).
- chr20:60,055,853–61,940,617, 17 genes, copy number 9–13 (within-gene range 3–13): C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
